Gene-level copy-number profile of tumor specimen HCM-SANG-0302-C15-08A-01D-A80T-32 from HCMI case HCM-SANG-0302-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0302-C15-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dbafdd34-d230-4520-9ef8-5c399f3730dc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0302-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/4294a43c-b89a-4f21-9d50-d23b1a5515ad

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 602; copy number 1: 52; copy number 2: 10,534; copy number 3: 27,118; copy number 4: 11,656; copy number 5: 3,582; copy number 6: 2,443; copy number 7: 1,257; copy number 8: 381; copy number 9: 67; copy number 10: 353; copy number 11: 555; copy number 12: 7; copy number 15: 15; copy number 16: 18; copy number 19: 135; copy number 20: 60; copy number 25: 22; copy number 27: 1; copy number 29: 35; copy number 36: 1; copy number 328: 2; copy number 368: 3; copy number 380: 1; copy number 585: 5.

Homozygous deletions (total copy number 0; autosomes only): 98 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–2): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr9:19,789,179–24,592,104, 85 genes (broad region; genes not listed).
- chr9:25,676,389–26,118,408, 4 genes: TUSC1, LINC01241, FAM71BP1, AL353753.1.
- chr10:75,552,458–75,552,553, 1 gene (within-gene range 0–3): MIR606.
- chr10:75,642,476–75,743,755, 2 genes (within-gene range 0–3): AL589863.1, AL731568.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,918 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,246,021–49,246,915, 2 genes, copy number 7: MTCO3P39, MTND3P22.
- chr6:41,405,819–49,273,794, 172 genes, copy number 7–36 (broad region; genes not listed).
- chr7:38,239,580–38,378,804, 24 genes, copy number 9 (within-gene range 6–9): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1.
- chr7:55,019,017–55,595,006, 11 genes, copy number 10–585: EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2.
- chr7:57,450,177–57,485,895, 2 genes, copy number 328: ZNF716, AC092175.1.
- chr8:7,926,337–7,952,413, 1 gene, copy number 7 (within-gene range 5–7): ZNF705B.
- chr8:7,955,014–9,556,520, 51 genes, copy number 7 (within-gene range 6–7): FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P, AC105233.1, AC105233.4, AC105233.2, MIR548I3, RPS3AP31, SNRPCP17, ENPP7P1, FAM85B, AC068020.1, FAM86B3P, ALG1L13P, PRAG1, AC103957.1, AC103957.2, AC114550.2, AC114550.3, AC114550.1, RN7SL178P, CLDN23, AC087269.1, MFHAS1, RNU6-682P, AC087763.1, RPL10P19, SNORA70, ERI1, MIR4660, RNU7-55P, Metazoa_SRP, PPP1R3B, AC022784.5, AC022784.1, AC022784.6, AC022784.2, AC022784.4, AC022784.3, RNU6-1151P, AC021736.1, AC021242.2, RNU6-526P, AC021242.1, AC021242.3.
- chr8:67,173,511–82,979,886, 233 genes, copy number 10–11 (within-gene range 6–11) (broad region; genes not listed).
- chr8:84,182,787–84,921,844, 4 genes, copy number 10 (within-gene range 6–10): RALYL, RNU6-1040P, PSMC2P2, AC009901.1.
- chr8:88,032,011–88,887,573, 4 genes, copy number 10 (within-gene range 6–10): MMP16, AC090578.1, RNA5SP272, AC090568.1.
- chr8:92,402,920–112,148,825, 330 genes, copy number 10–11 (broad region; genes not listed).
- chr8:116,845,934–128,564,679, 179 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).
- chr8:131,712,512–137,092,183, 61 genes, copy number 10 (broad region; genes not listed).
- chr8:139,096,305–143,417,054, 93 genes, copy number 10 (broad region; genes not listed).
- chr9:35,147,410–38,068,687, 96 genes, copy number 9–27 (within-gene range 4–27) (broad region; genes not listed).
- chr9:37,915,898–38,069,227, 1 gene, copy number 25 (within-gene range 4–25): SHB.
- chr11:41,714,534–42,253,721, 6 genes, copy number 7–9: LINC01499, AC023442.1, AC023442.3, AC023442.2, LINC02745, LINC02740.
- chr12:22,699,859–23,188,807, 1 gene, copy number 7 (within-gene range 3–7): AC084816.1.
- chr12:23,108,458–24,562,544, 5 genes, copy number 7 (within-gene range 6–7): AC087258.1, AC087235.2, AC087235.1, SOX5, AC087260.1.
- chr14:18,333,726–18,945,139, 27 genes, copy number 7: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11, CR383656.3, RPL22P20, CR383656.4, CR383656.2, NF1P10, NEK2P1, NF1P7, MED15P1, AL929601.1, AL929601.2.
- chr14:22,040,594–22,482,346, 46 genes, copy number 8 (within-gene range 5–8): TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54.
- chr14:22,547,506–22,552,156, 1 gene, copy number 8: TRAC.
- chr14:80,197,526–80,959,517, 3 genes, copy number 7 (within-gene range 3–7): DIO2, DIO2-AS1, CEP128.
- chr14:106,827,869–106,879,812, 8 genes, copy number 9: IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr17:39,252,663–40,527,002, 58 genes, copy number 20: FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867, WIPF2, CDC6, RARA, AC080112.4, RARA-AS1, AC080112.3, GJD3, AC080112.1, PPIAP54, RNA5SP441, AC080112.2, TOP2A, Y_RNA, RPL23AP75, IGFBP4, AC018629.1, TNS4, AC004585.1.
- chr18:45,034–4,455,307, 97 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr18:32,412,214–32,413,176, 1 gene, copy number 8 (within-gene range 6–8): HNRNPA1P7.
- chr18:32,511,663–32,514,634, 1 gene, copy number 8: WBP11P1.
- chr18:39,016,047–39,034,110, 2 genes, copy number 10: RN7SKP182, RNU6-706P.
- chr20:87,250–16,053,197, 288 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr20:15,280,764–64,327,972, 1,110 genes, copy number 7–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 38. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
